Somatic mutation profile of tumor specimen PCProject_0643_T2_WES (aliquot PCProject_0643_T2_WES_1) from CMI case PCProject_0643, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.0 years (20,823 days).
Specimen PCProject_0643_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 887658c6-eb15-4fc4-9985-42379c6b71bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0643_SALIVA (DNA), aliquot PCProject_0643_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1130d37-dbe6-4e9d-806e-5965e35f103d

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, 3'UTR 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP1 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 37/505 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV52850552; called by muse, mutect2
- HEATR5A | c.6140G>T p.*2047Lext*15 | Nonstop Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs1351072547; called by muse, varscan2
- HES5 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1178103718; called by muse, mutect2
- OR2G6 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs145771852; called by muse, mutect2
- TSC2 | c.4681A>G p.I1561V | Missense Mutation (SNP) | VAF 19/531 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- MIR124-2 | chr8:64378170 C>T | 5'Flank (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- TEX35 | c.543+18C>T | Intron (SNP) | VAF 21/198 reads (11%) | catalogued as rs578203168, COSV99274835; called by muse, mutect2, varscan2
- UMPS | c.*1362T>C | 3'UTR (SNP) | VAF 6/61 reads (10%) | called by muse, varscan2
